Somatic mutation profile of tumor specimen MP2PRT-PAPMIJ-TMP1-A (aliquot MP2PRT-PAPMIJ-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPMIJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,266 days).
Specimen MP2PRT-PAPMIJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b0856c5-3c8b-4c6c-ad15-ac93eeee0200.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPMIJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPMIJ-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8bbbbc3a-f1ec-4e39-965a-6a245adc53e1

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 2, In Frame Ins 2, Frame Shift Ins 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR7A2 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 204/467 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs868026798; called by muse, mutect2, varscan2
- DENND2A | c.2666G>T p.G889V | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.113); catalogued as COSV52059768; called by muse, mutect2, varscan2
- SPTSSB | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.659); catalogued as rs144350794, COSV100780643, COSV63218959; called by muse, mutect2, varscan2
- SWT1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 95/235 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs202090523; called by muse, mutect2, varscan2
- TSPYL4 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 157/349 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs757535016; called by muse, mutect2, varscan2
- ALX1 | c.797C>G p.S266* | Nonsense Mutation (SNP) | VAF 44/376 reads (12%) | called by muse, mutect2, varscan2
- B4GAT1 | c.373_374del p.F125Rfs*62 | Frame Shift Del (DEL) | VAF 119/720 reads (17%) | called by mutect2, pindel*, varscan2*
- BICC1 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 140/295 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- BTNL9 | c.499_500insTGGAA p.G167Vfs*7 | Frame Shift Ins (INS) | VAF 57/270 reads (21%) | called by mutect2, pindel, varscan2
- CC2D2A | c.2569G>C p.E857Q | Missense Mutation (SNP) | VAF 62/372 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- CFHR5 | c.1195C>G p.Q399E | Missense Mutation (SNP) | VAF 87/216 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- CPA4 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- CRISP3 | c.803C>T p.S268F (on ENST00000371159 / NM_001368123.1; = p.S250F on NM_006061.4) | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- EFCAB5 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- IGHV2-70 | c.357delinsTCTCCCC | In Frame Ins (INS) | VAF 80/197 reads (41%) | called by mutect2*, pindel, varscan2*
- PRPF38A | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SMCO3 | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 13/387 reads (3%) | called by muse, mutect2
- UBA2 | c.985_986insGGG p.L329delinsWV | In Frame Ins (INS) | VAF 87/262 reads (33%) | called by mutect2, pindel, varscan2
- FLNB | c.5754G>T p.V1918= | Silent (SNP) | VAF 24/374 reads (6%) | called by muse, mutect2
- HNF4G | c.804C>T p.I268= (on ENST00000354370 / NM_001330561.2; = p.I315= on NM_004133.5) | Silent (SNP) | VAF 131/290 reads (45%) | catalogued as rs748968405, COSV62966170, COSV62973661; called by muse, mutect2, varscan2
- POLR3B | c.3036G>A p.L1012= | Silent (SNP) | VAF 57/286 reads (20%) | called by muse, mutect2, varscan2
- SLC8A3 | c.186C>T p.I62= | Silent (SNP) | VAF 14/396 reads (4%) | called by muse, mutect2
- IGHV2-70 | chr14:106770576 ins GGGGGA | 3'Flank (INS) | VAF 29/92 reads (32%) | called by mutect2, varscan2
